Surgical pathology report (de-identified scan), TCGA case TCGA-B3-4103, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B3-4103-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Right kidney

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right renal mass.

GROSS DESCRIPTION

Received fresh labeled "right kidney" is a 491-gram, 10.5 x

8.5 x 4 cm right kidney with attached, Propaten, 5.5 cm ureter averaging 0.4 cm in diameter. A moderate amount of perirenal

adipose tissue was present. No adrenal gland is evident within the superior perirenal adipose tissue. The capsule is delicate and strips with relative ease from the underlying cortical surface. On sectioning there is a well-circumscribed, spherical, 3.7 cm soft tan-gold-red tumor centrally in the vicinity of the hilum. The lesion extends to within 0.1 cm of the inked capsular surface. A portion of tumor and a portion of normal parenchyma are submitted for tissue procurement, as requested. The remaining parenchyma is uniform, red-brown with a well-defined cortical medullary junction and a maximal cortical thickness of 1.5 cm. Multiple smooth-lined cortical cysts measuring up to 1.5 cm in diameter are present. No additional abnormalities are noted. Representative sections are submitted in 8 blocks, as labeled. RS-8.

BLOCK SUMMARY: 1 - Vascular and ureteral margins, 2-4 - lesion to inked capsular surface, 5 - lesion to normal parenchyma, 6 - renal pelvis, 7 and 8 - random for remainder of specimen documenting cortical cysts.

MICROSCOPIC DESCRIPTION

Histologic type: Papillary renal cell carcinoma.

Histologic grade (Fuhrman Nuclear Grade): 2 of 4

[page 2 of 2]
MICROSCOPIC DESCRIPTION

Primary tumor (pT): The tumor measures maximally 3.7 cm in size and

is confined to the kidney (pT1a).

Margins of resection: Negative.

Regional lymph nodes (pN): Cannot be assessed (pNX).

Distant metastasis (pM): Cannot be assessed (pMX).

Adrenal gland: Not present.

Vascular invasion: Negative.

Non-neoplastic kidney: Arteriolar nephrosclerosis. Benign cortical
cysts.

4

DIAGNOSIS

Kidney, right nephrectomy:

Papillary renal cell carcinoma (Fuhrman nuclear grade 2 of 4).

The tumor is confined to the kidney and does not extend beyond
the

renal capsule.

Vascular and ureteral margins of resection are unremarkable.

Benign cortical cysts.

Arteriolar nephrosclerosis.

--- End Of Report ---

Source: NCI Genomic Data Commons file 09951cd7-8964-4ad4-8843-114f21cb81ce (TCGA-B3-4103.DC2132AB-E2C7-4ED7-B3C2-E91BBEF84E5F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).